Gene-level copy-number profile of tumor specimen TCGA-DS-A3LQ-01A from TCGA case TCGA-DS-A3LQ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 46.2 years (16,861 days).
Specimen TCGA-DS-A3LQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.3eb07a33-4d0b-42fe-a681-459d5ae09a37.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DS-A3LQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d4127d02-e5f2-4b20-b22e-fa4f6a36adb6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,119; copy number 2: 27,126; copy number 3: 19,918; copy number 4: 6,224; copy number 5: 1,081; copy number 6: 596; copy number 7: 1,648; copy number 8: 7; copy number 9: 26; copy number 10: 1; copy number 13: 8; copy number 18: 29; copy number 35: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DS-A3LQ-01A-21D-A21P-01): tumor purity 0.72, ploidy 2.63, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,416 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:134,119,983–134,454,621, 1 gene, copy number 9 (within-gene range 1–9): MGAT5.
- chr2:134,319,654–134,918,710, 6 genes, copy number 9 (within-gene range 2–9): EDDM3CP, TMEM163, AC110620.2, CCNT2-AS1, VDAC2P4, AC110620.1.
- chr3:106,894,352–198,222,513, 1,648 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr4:53,377,839–55,636,698, 48 genes, copy number 9–18 (within-gene range 3–18): AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, AC021220.2, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU.
- chr5:45,890,216–45,895,970, 1 gene, copy number 10: AC122694.1.
- chr7:104,738,597–105,013,044, 6 genes, copy number 5 (within-gene range 3–5): LHFPL3-AS1, AC091286.1, LHFPL3-AS2, RN7SL8P, AC007384.1, LINC01004.
- chr9:60,914,407–97,122,489, 636 genes, copy number 5 (broad region; genes not listed).
- chr12:122,634,130–133,214,832, 322 genes, copy number 5 (broad region; genes not listed).
- chr14:18,333,726–31,488,039, 556 genes, copy number 6–35 (broad region; genes not listed).
- chr14:31,553,358–31,561,334, 2 genes, copy number 35: AL163973.3, AL163973.2.
- chr20:10,672,695–10,994,924, 1 gene, copy number 8 (within-gene range 4–8): AL050403.2.
- chr20:10,875,333–17,484,578, 72 genes, copy number 6–8 (within-gene range 4–8) (broad region; genes not listed).
- chr20:30,278,906–33,913,336, 117 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,348. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
